Somatic mutation profile of tumor specimen MMRF_1727_1_BM_CD138pos (aliquot MMRF_1727_1_BM_CD138pos_T1_KBS5U_L07225) from MMRF case MMRF_1727, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.9 years (26,264 days).
Specimen MMRF_1727_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 189ac76c-3391-47dd-9294-bc347c89055f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1727_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1727_1_PB_WBC_C3_KBS5U_L07226; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a81f9e4f-7a50-44d8-9b48-c9a49189d8ef

The open-access MAF lists 133 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 38, Intron 20, Silent 11, 5'UTR 6, 3'Flank 3, RNA 3, Splice Site 2, Nonsense Mutation 2, 5'Flank 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1436A>T p.D479V | Missense Mutation (SNP) | VAF 10/150 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2
- AGTPBP1 | c.1841C>T p.A614V (on ENST00000357081 / NM_001330701.2; = p.A574V on NM_015239.2) | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1204618567; called by muse, mutect2
- ANKRD22 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs201744509; called by muse, mutect2
- ASIC5 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs147885015; called by muse, mutect2
- COL1A1 | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56803746; called by muse, mutect2
- DSP | c.5795G>A p.R1932H | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs770522444, COSV65792506; called by muse, mutect2, varscan2
- IGHV3-74 | c.105dup p.S36Vfs*15 | Frame Shift Ins (INS) | VAF 28/213 reads (13%) | catalogued as rs756790234; called by pindel, varscan2
- IGLV3-19 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as rs376663286; called by muse, varscan2
- IGLV3-19 | c.319A>T p.N107Y | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as rs182162941; called by muse, mutect2, varscan2
- LONP2 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469632804; called by muse, mutect2, varscan2
- LRIT3 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254075499; called by muse, mutect2
- MUL1 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs776763974; called by muse, mutect2, varscan2
- NEUROG1 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59082211; called by muse, mutect2, varscan2
- REV3L | c.2035A>C p.T679P | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV62615218; called by muse, mutect2, varscan2
- RIF1 | c.4785A>G p.I1595M | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1559016981; called by muse, mutect2, varscan2
- TMEM151A | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs1183992250, COSV59173888; called by muse, mutect2, varscan2
- TP63 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53211769; called by muse, mutect2, varscan2
- ZSCAN5A | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.93); catalogued as COSV99569835; called by muse, mutect2
- CMBL | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2
- CNTD1 | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CPNE5 | c.1625T>G p.L542R | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX35 | c.1242G>T p.L414F | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- DNAH3 | c.8315C>A p.A2772D | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- EIF3G | c.595+1G>A p.X199_splice | Splice Site (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- FCGBP | c.2813A>T p.Y938F | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.196); called by muse, mutect2
- GEN1 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GRID2 | c.654A>C p.E218D | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HELB | c.757T>C p.W253R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA7 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HTR1E | c.244T>A p.Y82N | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV3-25 | c.322T>G p.S108A | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, varscan2
- IL1R1 | c.1310T>C p.V437A | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ITGA10 | c.2477T>C p.V826A | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- KCNK2 | c.622G>T p.E208* (on ENST00000444842 / NM_001017425.3; = p.E193* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 59/554 reads (11%) | called by muse, mutect2, varscan2
- LRRC74A | c.772T>G p.F258V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MTA2 | c.1361T>C p.F454S | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MUC5AC | c.1808A>G p.Q603R | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.07); called by muse, mutect2
- MYBPC1 | c.2931A>C p.E977D (on ENST00000550270 / NM_206820.2; = p.E984D on NM_002465.4) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR52H1 | c.851T>A p.V284D (on ENST00000322653; = p.V290D on NM_001005289.1) | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PDZD8 | c.2999A>T p.K1000M | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHLDA2 | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRKCD | c.1958_1981del p.D653_F660del | In Frame Del (DEL) | VAF 53/420 reads (13%) | called by mutect2, pindel
- RABGAP1L | c.2212-16_2242del p.X738_splice | Splice Site (DEL) | VAF 68/454 reads (15%) | called by mutect2, pindel
- RPS6 | c.299G>C p.C100S | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- RTCA | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPAG16 | c.1326C>A p.C442* | Nonsense Mutation (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- TREX2 | c.536C>T p.A179V (on ENST00000334497; = p.A136V on NM_080701.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- TTN | c.53300G>A p.G17767D (on ENST00000591111; = p.G10343D on NM_003319.4) | Missense Mutation (SNP) | VAF 9/135 reads (7%) | PolyPhen probably damaging (0.974); called by muse, mutect2
- TTYH1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.055); called by muse, mutect2
- USP39 | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ANKFN1 | c.2247C>T p.L749= | Silent (SNP) | VAF 40/443 reads (9%) | called by muse, mutect2
- GAD2 | c.1395C>T p.T465= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs753339116, COSV52165019, COSV99393726; called by muse, mutect2, varscan2
- IGHV2-70 | c.90G>A p.L30= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs564942249; called by muse, varscan2
- IGHV2-70D | c.225T>C p.D75= | Silent (SNP) | VAF 15/48 reads (31%) | called by muse, varscan2
- IGHV3-74 | c.99T>C p.P33= | Silent (SNP) | VAF 42/212 reads (20%) | called by muse, varscan2
- IVNS1ABP | c.669G>A p.L223= | Silent (SNP) | VAF 76/145 reads (52%) | called by muse, mutect2, varscan2
- KCNC4 | c.1599C>T p.I533= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs770979171, COSV100873708, COSV63925104; called by muse, mutect2, varscan2
- KRTAP5-10 | c.255T>C p.G85= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs12793134; called by muse, varscan2
- OR5D16 | c.618T>C p.T206= | Silent (SNP) | VAF 53/412 reads (13%) | called by muse, mutect2, varscan2
- RRP12 | c.645C>T p.S215= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- TDO2 | c.12C>T p.C4= | Silent (SNP) | VAF 110/462 reads (24%) | catalogued as COSV72232999; called by muse, mutect2, varscan2
- ABLIM2 | c.1516+1009T>G | Intron (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- AC073348.1 | n.143T>C | RNA (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- AC124067.4 | n.2128C>T | RNA (SNP) | VAF 15/357 reads (4%) | catalogued as rs1366783653; called by muse, mutect2
- ADAMTS5 | c.*2055dup | 3'UTR (INS) | VAF 23/157 reads (15%) | called by mutect2, pindel, varscan2
- AK2 | c.-92G>A | 5'UTR (SNP) | VAF 23/86 reads (27%) | catalogued as rs1409459518; called by muse, mutect2, varscan2
- AR | c.1885+9177A>G | Intron (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- ATAD2B | c.*933T>C | 3'UTR (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- B3GALT5 | c.-523-7351A>G | Intron (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- BAK1 | c.*1076A>G | 3'UTR (SNP) | VAF 17/231 reads (7%) | called by muse, mutect2
- BCL7A | chr12:122021358 del CTAGTTTTCCAAAAGGACAAAG | 5'Flank (DEL) | VAF 16/101 reads (16%) | called by mutect2, pindel
- BTBD7 | c.1162+5605G>A | Intron (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- CAND1 | c.-151G>T | 5'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- CDYL | c.*473G>A | 3'UTR (SNP) | VAF 15/72 reads (21%) | catalogued as rs1379793407; called by muse, mutect2, varscan2
- CHRAC1 | c.*1657C>A | 3'UTR (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- CNPY1 | c.*1763C>G | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- CTPS1 | c.-36T>C | 5'UTR (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- DAAM1 | c.*1135A>G | 3'UTR (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- DCHS2 | n.2023G>T | RNA (SNP) | VAF 31/220 reads (14%) | called by muse, mutect2, varscan2
- DENND1C | c.1583+31A>T | Intron (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- EFCAB11 | c.*389G>T | 3'UTR (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- EMC3 | c.-176G>A | 5'UTR (SNP) | VAF 66/396 reads (17%) | called by muse, mutect2, varscan2
- GAD2 | c.*35-1223A>C | Intron (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- GAPDH | c.29+135G>C | Intron (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- GATC | c.*145G>T | 3'UTR (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- GNGT2 | c.-1G>T | 5'UTR (SNP) | VAF 31/390 reads (8%) | called by muse, mutect2
- GOLPH3L | c.*1243C>G | 3'UTR (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2
- GPR63 | c.*180T>G | 3'UTR (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- GRIA4 | c.1269+1541A>G | Intron (SNP) | VAF 46/170 reads (27%) | called by muse, mutect2, varscan2
- GULP1 | c.844-1091A>C | Intron (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- H2BC14 | c.*23C>T | 3'UTR (SNP) | VAF 35/241 reads (15%) | catalogued as rs762544360; called by muse, mutect2, varscan2
- HNRNPM | c.2029+61T>G | Intron (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- IKZF2 | c.*144G>T | 3'UTR (SNP) | VAF 7/193 reads (4%) | called by muse, mutect2
- KBTBD3 | c.*1582A>C | 3'UTR (SNP) | VAF 45/201 reads (22%) | called by muse, mutect2, varscan2
- KCNMB2 | c.*1480dup | 3'UTR (INS) | VAF 14/101 reads (14%) | catalogued as rs201642652; called by mutect2, varscan2
- KLHL24 | c.*1581A>C | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- KMT5B | c.1174+568T>C | Intron (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- KRT78 | c.*356T>C | 3'UTR (SNP) | VAF 19/111 reads (17%) | catalogued as rs369805687; called by muse, mutect2, varscan2
- LDLRAP1 | c.533-84A>C | Intron (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- LILRA2 | c.*223T>A | 3'UTR (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- MAPRE2 | c.*408G>A | 3'UTR (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- MIR5195 | chr14:106851350 C>A | 5'Flank (SNP) | VAF 29/143 reads (20%) | catalogued as rs1423144964; called by muse, mutect2, varscan2
- NCKAP5 | c.*1351G>T | 3'UTR (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- NKD2 | c.788-218C>T | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as rs757675303; called by muse, mutect2, varscan2
- NLGN4Y | c.473-3633C>T | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- OMD | c.*591T>A | 3'UTR (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- OR4D1 | chr17:58157787 A>G | 3'Flank (SNP) | VAF 18/414 reads (4%) | catalogued as COSV52125516; called by muse, mutect2
- PAQR8 | c.*3374A>T | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- PAX7 | c.*2057C>T | 3'UTR (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- PCDH10 | c.-600G>T | 5'UTR (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.2206-169A>G | Intron (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- PTAR1 | c.*5731C>T | 3'UTR (SNP) | VAF 27/110 reads (25%) | called by muse, mutect2, varscan2
- PTPN20 | chr10:47001378 G>C | 3'Flank (SNP) | VAF 15/307 reads (5%) | catalogued as rs1418612104; called by muse, mutect2
- RAB8B | c.*2051T>A | 3'UTR (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- RIMS3 | chr1:40623511 C>T | 3'Flank (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- RPL37A | c.133-52G>A | Intron (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- S100A14 | c.*434C>A | 3'UTR (SNP) | VAF 61/211 reads (29%) | called by muse, mutect2, varscan2
- SELENOI | c.*972C>T | 3'UTR (SNP) | VAF 13/161 reads (8%) | called by muse, mutect2
- SLC37A3 | c.*1331C>T | 3'UTR (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.*1306G>C | 3'UTR (SNP) | VAF 5/139 reads (4%) | called by muse, mutect2
- SORCS2 | c.*981C>A | 3'UTR (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- SRSF5 | c.297-140A>G | Intron (SNP) | VAF 27/154 reads (18%) | catalogued as rs1484222939; called by muse, mutect2, varscan2
- STX18 | c.*235C>T | 3'UTR (SNP) | VAF 26/119 reads (22%) | catalogued as rs1464280459; called by muse, mutect2, varscan2
- TMCC1 | c.*1079G>A | 3'UTR (SNP) | VAF 11/165 reads (7%) | catalogued as rs1407423114; called by muse, mutect2
- TOLLIP | c.*1999G>C | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- TRIM14 | c.*842G>A | 3'UTR (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- UBXN10 | c.*2475A>C | 3'UTR (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- UNC80 | c.7932+156C>G | Intron (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- ZBTB44 | c.*1836G>T | 3'UTR (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- ZNF140 | c.233-4476C>T | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- ZNF385D | c.*1989G>A | 3'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- ZNF528 | c.*208G>T | 3'UTR (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- ZNF8 | c.66+444G>C | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
